Surgical pathology report (de-identified scan), TCGA case TCGA-85-6560, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-6560-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

Case ID	[REDACTED]	Formatted Path Report
		LUNG TISSUE CHECKLIST Specimen type: Pneumonectomy Tumor site: Lung Tumor size: 3 x 2.5 x 2 cm Histologic type: Squamous cell carcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 2/12 positive for metastasis (Hilar 2/12) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[REDACTED]

[page 2 of 2]
Date of Procurement	

Source: NCI Genomic Data Commons file 85046ed3-4061-4837-a211-eb232bdb4fb9 (TCGA-85-6560.DE1A9413-405B-4F15-BA7F-062AE63EA44B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).